Surgical pathology report (de-identified scan), TCGA case TCGA-ZF-AA4W, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Sheffield, specimen TCGA-ZF-AA4W-01A (Primary Tumor).

[page 1 of 2]
Histopathology Histopathology

Specimen Comments

SPECIMEN

1. Bladder
2. External iliac right
3. Internal iliac right
4. Obturator node right
5. Left obturator node and internal iliac
6. Right pararectal lymph node
7. Right internal iliac artery
8. Left ureteric resection margin
9. Right ureteric resection margin

CLINICAL DETAILS

Carcinoma of the bladder in diverticulum. Cystectomy done.

MACROSCOPY

1. Specimen consists of bladder (160 x 65 x 37mm), prostate and peri-vesical fat, entire specimen measuring 125 x 120 x 45mm. The right lateral wall contains an ulcerated tumour (22mm maximum dimension) which appears to extend to the full thickness of the wall to reach the fat. The lesion is within 2mm of the circumferential surgical resection margin. The prostate appears macroscopically normal. No lymph nodes are identified in the fat.
2. Lymph node measuring 26 x 8 x 5mm.
3. The specimen consists of fragmented nodal tissue measuring 40 x 20 x 8mm plus fat.
4. Fatty tissue measuring 55 x 50 x 10mm containing 3 nodes, the largest 23mm in maximum dimension.
5. Fatty tissue measuring 60 x 50 x 15mm. The largest node measures 25mm in maximum dimension.
6. Fibrofatty tissue measuring 15 x 15 x 5mm.
7. Cylindrical piece of tissue 23mm in length x up to 4mm diameter.
8. Piece of tissue 15 x 5 x 3mm.
9. Cylindrical piece of tissue 15mm in length x 3mm diameter.

MICROSCOPY

1. Sections taken from the macroscopically identified tumour show a poorly differentiated transitional cell carcinoma with a significant lipoid cell component, extending through the bladder wall to reach the perivesicle fat. Areas of necrosis are noted. Extensive perineural invasion is seen. There is some possible lymphovascular invasion.
The tumour host interface contains only a sparse lymphocytic infiltrate. The overlying epithelium is largely denuded, but where present, is morphologically normal with no evidence of dysplasia or carcinoma in situ. Random sections from the rest of the bladder wall shows morphologically normal urothelium.
The sections from both lobes of the prostate are morphologically normal. The prostatic urethral resection margin shows no evidence of tumour or dysplasia.
2. External iliac right; Reactive lymph node with no evidence of metastatic carcinoma.

C679 ICD O-3
Carcinoma, urothelial NOS 8/20/13
Carcinoma, transitional cell NOS 8/20/13
Site: Bladder NOS C679
JAS 4/30/14

[page 2 of 2]
3. Right internal iliac; A reactive lymph node with no evidence of metastatic carcinoma.
4. Right obturator node; Three reactive nodes with no evidence of metastatic carcinoma.
5. Left obturator node and internal iliac; Nine reactive nodes with no evidence of metastatic carcinoma.
6. Right para rectal lymph node; A lymph node with no evidence of metastatic carcinoma.
7. Right internal iliac artery; Sections confirm a muscular artery with medial degeneration and dystrophic calcification. There is no evidence of carcinoma.
8. Left ureteric resection; All the tissue was processed and shows ureteric tissue largely denuded of urothelium. There is no evidence of invasive transitional cell carcinoma.
9. Right ureteric resection margin; Ureteric tissue denuded of urothelium but with surface ulceration lined by granulation tissue. The lamina propria is oedematous and congested with a moderate chronic inflammatory cell infiltrate. There is no evidence of urothelial carcinoma.

SUMMARY

Bladder and lymph nodes; The appearances are those of a poorly differentiated transitional cell carcinoma extending into perivesicle fat. No evidence of nodal disease. pT3b pN0 pMx

Ref:

Pathologists -

Source: NCI Genomic Data Commons file a6b7986b-ea9f-4c04-9e71-990380b1e681 (TCGA-ZF-AA4W.CEDD5865-4B14-4F0C-9BBD-CBE89E68C2C3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).